Somatic mutation profile of tumor specimen TCGA-28-5208-01A (aliquot TCGA-28-5208-01A-01D-1486-08) from TCGA case TCGA-28-5208, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 52.2 years (19,053 days).
Specimen TCGA-28-5208-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1bc4fe25-5368-486b-b3b2-c64f03a58d6d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-28-5208-10A (Blood Derived Normal), aliquot TCGA-28-5208-10A-01D-1486-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4ebacb5d-3778-4923-b871-b1ce7a849bdf

The open-access MAF lists 56 somatic variants for this specimen: 46 protein-altering or splice-affecting, 10 silent.
By variant classification: Missense Mutation 43, Silent 10, Nonsense Mutation 2, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NF1 | c.1381C>T p.R461* | Nonsense Mutation (SNP) | VAF 102/269 reads (38%) | hotspot (GDC flag); catalogued as rs878853865, CM000780, COSV62194747; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCG5 | c.1124T>C p.V375A | Missense Mutation (SNP) | VAF 64/137 reads (47%) | SIFT tolerated (0.15); PolyPhen benign (0.334); catalogued as COSV53211147; called by muse, mutect2, varscan2
- ACTL9 | c.622G>A p.V208I | Missense Mutation (SNP) | VAF 63/167 reads (38%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.999); catalogued as rs139329295, COSV61005953; called by muse, mutect2, varscan2
- AFF2 | c.2609G>A p.R870H | Missense Mutation (SNP) | VAF 294/349 reads (84%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as rs782806508, COSV53991574; called by muse, mutect2, varscan2
- ANLN | c.1948A>G p.R650G | Missense Mutation (SNP) | VAF 243/473 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV56076676; called by muse, mutect2, varscan2
- APBB1 | c.1237T>C p.S413P | Missense Mutation (SNP) | VAF 94/214 reads (44%) | SIFT tolerated (0.19); PolyPhen benign (0.355); catalogued as COSV54976364; called by muse, mutect2, varscan2
- APLF | c.176C>G p.T59R | Missense Mutation (SNP) | VAF 90/198 reads (45%) | SIFT tolerated (0.05); PolyPhen benign (0.006); catalogued as COSV58145108; called by muse, mutect2, varscan2
- ASB2 | c.1514C>T p.A505V | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.629); catalogued as rs765782110, COSV60112128; called by muse, mutect2, varscan2
- ATN1 | c.2633C>T p.P878L | Missense Mutation (SNP) | VAF 89/202 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV63111192; called by muse, mutect2, varscan2
- AVPR2 | c.883G>A p.A295T | Missense Mutation (SNP) | VAF 12/160 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.871); catalogued as rs781875789, COSV61686308; called by muse, mutect2
- AXDND1 | c.812G>A p.R271Q | Missense Mutation (SNP) | VAF 69/212 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs764766519, COSV62642191, COSV62643287; called by muse, mutect2, varscan2
- CACNA2D1 | c.296G>A p.R99H | Missense Mutation (SNP) | VAF 42/456 reads (9%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as rs562957992, COSV62380645; called by muse, mutect2
- CACNA2D3 | c.3151C>T p.R1051C | Missense Mutation (SNP) | VAF 27/72 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs1256070064, COSV55543405; called by muse, mutect2, varscan2
- CPNE7 | c.569C>T p.T190M | Missense Mutation (SNP) | VAF 8/13 reads (62%) | SIFT tolerated (0.15); PolyPhen benign (0.014); catalogued as rs202128349, COSV52013121; called by muse, mutect2, varscan2
- EIF3J | c.563G>A p.C188Y | Missense Mutation (SNP) | VAF 90/223 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56008886; called by muse, mutect2, varscan2
- FGD3 | c.1591C>T p.R531C | Missense Mutation (SNP) | VAF 59/127 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs780003397, COSV61597661; called by muse, mutect2, varscan2
- GRIN2A | c.1225G>A p.V409I | Missense Mutation (SNP) | VAF 91/246 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.864); catalogued as rs1351978664, COSV58035584; called by muse, mutect2, varscan2
- ITLN1 | c.239C>A p.T80N | Missense Mutation (SNP) | VAF 60/151 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58275348; called by muse, mutect2, varscan2
- L1CAM | c.2839G>A p.V947M | Missense Mutation (SNP) | VAF 36/42 reads (86%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.753); catalogued as rs1302912544, COSV62828061; called by muse, mutect2, varscan2
- LRRC37A3 | c.93G>C p.W31C | Missense Mutation (SNP) | VAF 54/322 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as COSV59761725; called by muse, varscan2
- MMRN1 | c.2402A>C p.Q801P | Missense Mutation (SNP) | VAF 74/176 reads (42%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.77); catalogued as COSV53338024; called by muse, mutect2, varscan2
- NF1 | c.1865G>T p.C622F | Missense Mutation (SNP) | VAF 155/381 reads (41%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.011); catalogued as COSV62205365; called by muse, mutect2, varscan2
- NOS1 | c.1255C>T p.R419C | Missense Mutation (SNP) | VAF 75/209 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs913433943, COSV57609864; called by muse, mutect2, varscan2
- NOTCH4 | c.3025G>A p.E1009K | Missense Mutation (SNP) | VAF 28/71 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as rs1017602752, COSV66681038, COSV66682600; called by muse, mutect2, varscan2
- OR4D5 | c.787C>T p.R263W | Missense Mutation (SNP) | VAF 125/331 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.773); catalogued as rs141929562; called by muse, mutect2, varscan2
- OR8H3 | c.363T>G p.D121E | Missense Mutation (SNP) | VAF 230/574 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57909239; called by muse, mutect2, varscan2
- PCLO | c.1616C>A p.P539H | Missense Mutation (SNP) | VAF 276/664 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.912); catalogued as COSV61638673; called by muse, mutect2, varscan2
- PI4KB | c.1952G>A p.R651H (on ENST00000368873 / NM_001369623.1; = p.R663H on NM_002651.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 241/549 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.608); catalogued as rs1190417371, COSV55017128, COSV55020083; called by muse, mutect2, varscan2
- PVR | c.499G>A p.V167I | Missense Mutation (SNP) | VAF 20/442 reads (5%) | SIFT tolerated (0.37); PolyPhen benign (0.063); catalogued as rs754527739, COSV51823254; called by muse, mutect2
- QKI | c.295del p.V99Lfs*31 | Frame Shift Del (DEL) | VAF 60/208 reads (29%) | catalogued as COSV51701426; called by mutect2, pindel, varscan2
- SAMD9L | c.1527T>G p.Y509* | Nonsense Mutation (SNP) | VAF 136/338 reads (40%) | catalogued as COSV59081995; called by muse, mutect2, varscan2
- SENP7 | c.332G>A p.R111Q | Missense Mutation (SNP) | VAF 85/188 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1219140542, COSV58612749; called by muse, mutect2, varscan2
- SETD2 | c.6365G>A p.R2122Q | Missense Mutation (SNP) | VAF 80/200 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV57436714, COSV57438944; called by muse, mutect2, varscan2
- SNTG2 | c.559G>A p.G187S | Missense Mutation (SNP) | VAF 167/426 reads (39%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.579); catalogued as rs567910526, COSV57967089; called by muse, mutect2, varscan2
- SOWAHB | c.1186G>A p.D396N | Missense Mutation (SNP) | VAF 140/342 reads (41%) | SIFT tolerated (0.07); PolyPhen benign (0.052); catalogued as COSV100530576, COSV57554584; called by muse, mutect2, varscan2
- TCN1 | c.322G>A p.A108T | Missense Mutation (SNP) | VAF 100/268 reads (37%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs757531697, COSV57252762, COSV57252768, COSV57254199; called by muse, mutect2, varscan2
- TLR7 | c.2860G>A p.V954M | Missense Mutation (SNP) | VAF 247/285 reads (87%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); catalogued as COSV66124426; called by muse, mutect2, varscan2
- TMEM132E | c.949C>T p.R317W (on ENST00000321639; = p.R407W on NM_001304438.2) | Missense Mutation (SNP) | VAF 80/189 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs371393529, COSV58695340; called by muse, mutect2, varscan2
- TMEM61 | c.511G>A p.A171T | Missense Mutation (SNP) | VAF 114/268 reads (43%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs527691651, COSV64873373; called by muse, mutect2, varscan2
- TPD52L3 | c.166C>T p.R56C | Missense Mutation (SNP) | VAF 57/87 reads (66%) | SIFT deleterious (0.04); PolyPhen benign (0.117); catalogued as rs757070996, COSV58828402; called by muse, mutect2, varscan2
- TRPM6 | c.1577G>A p.R526H | Missense Mutation (SNP) | VAF 109/308 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as rs1407266718, COSV62511825; called by muse, mutect2, varscan2
- WNT9A | c.389C>T p.S130L | Missense Mutation (SNP) | VAF 63/138 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs1305243960, COSV55295083, COSV99687964; called by muse, mutect2, varscan2
- ZNF236 | c.5465G>T p.S1822I | Missense Mutation (SNP) | VAF 100/243 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.063); catalogued as COSV53489361; called by muse, mutect2, varscan2
- ZNF335 | c.2155C>T p.R719C | Missense Mutation (SNP) | VAF 55/151 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs763158895, COSV59815833; called by muse, mutect2, varscan2
- ZNF532 | c.1738G>A p.V580M | Missense Mutation (SNP) | VAF 29/68 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs372233148; called by muse, mutect2, varscan2
- ZNF813 | c.785G>A p.R262H | Missense Mutation (SNP) | VAF 69/283 reads (24%) | SIFT tolerated (0.33); PolyPhen benign (0.031); catalogued as rs766270427, COSV67176660; called by muse, mutect2, varscan2
- ALPG | c.1410C>T p.G470= | Silent (SNP) | VAF 24/50 reads (48%) | catalogued as rs768493692, COSV54966318; called by muse, mutect2, varscan2
- CHRDL1 | c.1140C>T p.L380= (on ENST00000372045; = p.L386= on NM_145234.4) | Silent (SNP) | VAF 74/92 reads (80%) | catalogued as COSV54325036; called by muse, mutect2, varscan2
- MGA | c.8004C>T p.G2668= (on ENST00000219905 / NM_001164273.1; = p.G2459= on NM_001080541.2) | Silent (SNP) | VAF 65/179 reads (36%) | catalogued as COSV54955135; called by muse, mutect2, varscan2
- ODF3 | c.126G>A p.T42= | Silent (SNP) | VAF 28/87 reads (32%) | catalogued as rs374039790; called by muse, mutect2, varscan2
- OR5D16 | c.486G>A p.A162= | Silent (SNP) | VAF 72/199 reads (36%) | catalogued as rs201981572, COSV65721949; called by muse, mutect2, varscan2
- PCDHA1 | c.1854G>A p.A618= | Silent (SNP) | VAF 95/195 reads (49%) | catalogued as rs543937372, COSV65374214; called by muse, mutect2, varscan2
- PCDHGA4 | c.1761C>T p.N587= | Silent (SNP) | VAF 231/528 reads (44%) | catalogued as rs756682784, COSV53937153; called by muse, mutect2, varscan2
- TECTA | c.552C>T p.Y184= | Silent (SNP) | VAF 59/133 reads (44%) | catalogued as rs148364865; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TSHR | c.1623C>T p.I541= | Silent (SNP) | VAF 88/210 reads (42%) | catalogued as COSV53321221; called by muse, mutect2, varscan2
- UCKL1 | c.1383G>A p.A461= | Silent (SNP) | VAF 12/49 reads (24%) | catalogued as COSV62402963; called by muse, mutect2, varscan2
